Gene-level copy-number profile of tumor specimen TCGA-D7-6519-01A from TCGA case TCGA-D7-6519, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Cardia, NOS; Tumor grade: G3; Age at diagnosis: 64.1 years (23,413 days).
Specimen TCGA-D7-6519-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.9676e70e-320a-49d2-a760-cfa0da7cec42.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D7-6519-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5765b447-c4bf-44ec-85c1-09c9fedbc101

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 52; copy number 1: 151; copy number 2: 22,453; copy number 3: 6,788; copy number 4: 27,703; copy number 5: 1,624; copy number 6: 841; copy number 7: 41; copy number 8: 14; copy number 12: 1; copy number 18: 5; copy number 19: 34; copy number 20: 67; copy number 26: 25; copy number 29: 15.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D7-6519-01A-11D-1799-01): tumor purity 0.74, ploidy 3.28, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 50 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:36,703,953–36,710,582, 1 gene: AL596257.1.
- chr2:141,167,257–141,167,357, 1 gene: RNU6-904P.
- chr3:46,017,007–46,485,234, 12 genes (within-gene range 0–3): XCR1, NRBF2P2, FLT1P1, CCR3, CCR1, UQCRC2P1, CCR2, CCR5AS, CCR5, CCRL2, LINC02009, LTF.
- chr3:49,887,002–50,100,045, 5 genes (within-gene range 0–2): MST1R, AC105935.2, AC105935.1, MON1A, RBM6.
- chr3:59,464,330–59,584,445, 3 genes: AC126121.2, AC126121.1, Metazoa_SRP.
- chr3:59,809,269–59,811,310, 1 gene: AC093418.1.
- chr6:156,774,217–157,210,779, 7 genes: AL355297.2, ARID1B, AL355297.3, MIR4466, AL355297.1, AL162578.1, AL049820.1.
- chr9:9,442,060–9,442,380, 1 gene: RN7SL5P.
- chr9:21,966,929–21,995,301, 2 genes: CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,012,536, 3 genes: AL449423.1, CDKN2B, UBA52P6.
- chr9:109,375,466–110,172,512, 5 genes (within-gene range 0–2): PTPN3, PALM2AKAP2, MIR3927, YBX1P6, AL158829.1.
- chr16:6,573,767–6,748,969, 4 genes: AC007223.1, AC007012.2, AC007012.1, RNU7-99P.
- chr18:8,133,203–8,367,034, 3 genes: AC006566.2, AC006566.1, AP001094.3.
- chr21:34,723,807–34,784,886, 2 genes: LINC00160, LINC01426.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 147 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:94,937,980–96,245,335, 5 genes, copy number 18 (within-gene range 6–18): LINC00879, RPS18P6, MTHFD2P1, AC106719.1, AC107304.1.
- chr12:24,566,964–26,335,856, 43 genes, copy number 20 (within-gene range 8–20): LINC00477, KNOP1P1, AC087312.1, AC023796.1, RN7SL38P, BCAT1, AC023796.2, AC026310.2, AC026310.1, BRI3P2, C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2, AC087239.1, RNU4-67P, AC092451.1, LMNTD1, AC092451.2, FAM133GP, TUBB4BP1, AC022367.1, RN7SKP262, AC019209.3, TDGP1, AC019209.2, MIR4302, AC019209.1, RASSF8-AS1, RASSF8, BHLHE41, SSPN, AC022509.3, AC022509.5, AC022509.2, AC022509.1, AC022509.4.
- chr12:64,883,394–67,069,162, 40 genes, copy number 12–29 (within-gene range 2–29): LINC02389, LINC02231, RNU6ATAC42P, AC135895.1, WIF1, RNU6-166P, APOOP3, LEMD3, AC026124.2, MSRB3, AC026124.1, KRT18P60, AC025419.1, AC090023.1, LINC02454, AC090023.2, PCNPP3, RPSAP52, HMGA2, AC107308.1, HMGA2-AS1, AC090673.1, MIR6074, LINC02425, RPL21P18, RNA5SP362, LLPH, AC078927.1, LLPH-DT, TMBIM4, IRAK3, RBMS1P1, MIR6502, AC078889.1, PDCL3P7, RN7SKP166, HELB, GRIP1, OSBPL9P5, OSBPL9P4.
- chr12:67,424,272–69,610,907, 59 genes, copy number 19–26: NTAN1P3, LINC02420, LINC02408, LINC02442, DYRK2, AC078777.1, LINC02421, AC022513.1, LINC01479, AC005294.1, IFNG-AS1, RPL39P28, HNRNPA1P70, AC007458.1, IFNG, IL26, IL22, MDM1, LINC02384, AC022511.1, AC008033.3, AC008033.1, AC008033.2, RPSAP12, Metazoa_SRP, RAP1B, RPL10P12, SNORA70G, ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10.

Autosomal genes at a single copy (total copy number 1): 149. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
